Somatic mutation profile of tumor specimen ALCH-B1QB-TTP1-A (aliquot ALCH-B1QB-TTP1-A-3-0-D-A76I-36) from ALCHEMIST case ALCH-B1QB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.7 years (24,720 days).
Specimen ALCH-B1QB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8988d52c-b393-4774-b9ef-e6596712d481.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1QB-NB1-A (Blood Derived Normal), aliquot ALCH-B1QB-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbbd46db-082e-4608-8055-8681c19440f4

The open-access MAF lists 48 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, Intron 6, RNA 2, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 452/869 reads (52%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 72/247 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY5 | c.2941G>A p.A981T | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.065); catalogued as rs571005355; called by muse, mutect2, varscan2
- CEACAM18 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs570397427, COSV104433688; called by muse, mutect2, varscan2
- CECR2 | c.1804C>T p.R602* (on ENST00000342247 / NM_001290047.2; = p.R419* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 12/174 reads (7%) | catalogued as COSV52844067; called by muse, mutect2
- DLL1 | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 54/618 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs759299011, COSV64538240; called by muse, mutect2
- FAM171B | c.1748C>T p.T583M | Missense Mutation (SNP) | VAF 54/428 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.24); catalogued as rs369639086; called by muse, mutect2, varscan2
- IGHV1-46 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 83/574 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs531889359; called by muse, mutect2, varscan2
- PCDHGA12 | c.1025A>T p.D342V | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as rs1210499024, COSV52747084; called by muse, mutect2, varscan2
- SCAPER | c.16C>G p.Q6E | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57750643; called by muse, mutect2, varscan2
- TRNAU1AP | c.846G>C p.E282D | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1340724851, COSV100867855; called by muse, mutect2, varscan2
- URB2 | c.20G>A p.G7D | Missense Mutation (SNP) | VAF 40/279 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs779299168; called by muse, mutect2, varscan2
- ALOXE3 | c.884G>A p.S295N | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2
- ATXN7L2 | c.1058G>C p.S353T | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); called by muse, mutect2
- CCDC28A | c.78A>C p.K26N | Missense Mutation (SNP) | VAF 70/650 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.796); called by mutect2, varscan2
- CLDN17 | c.139T>C p.W47R | Missense Mutation (SNP) | VAF 57/608 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DNAH9 | c.12069T>G p.H4023Q | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GART | c.1621G>A p.G541R | Missense Mutation (SNP) | VAF 42/466 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GTF2H1 | c.1483A>C p.S495R | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- MYH6 | c.3941T>G p.M1314R | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NCOR1 | c.3571C>G p.P1191A | Missense Mutation (SNP) | VAF 20/361 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- OR2T33 | c.443T>A p.L148H | Missense Mutation (SNP) | VAF 90/784 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PDE2A | c.2339T>C p.L780P | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PREX1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- RBM47 | c.463A>T p.I155F | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- TANC2 | c.408C>A p.S136R | Missense Mutation (SNP) | VAF 41/373 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- TMEM204 | c.402G>A p.W134* | Nonsense Mutation (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- UMODL1 | c.2989A>C p.K997Q (on ENST00000408910 / NM_001004416.2; = p.K1125Q on NM_173568.3) | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); called by muse, mutect2
- USP36 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 81/471 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP43 | c.2776C>T p.P926S | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.895); called by muse, mutect2
- ZNF292 | c.2615T>C p.L872P | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAVIN1 | c.339G>A p.K113= | Silent (SNP) | VAF 40/226 reads (18%) | called by muse, mutect2, varscan2
- CCDC86 | c.90G>A p.R30= | Silent (SNP) | VAF 29/193 reads (15%) | called by muse, mutect2, varscan2
- COL6A5 | c.7326G>A p.V2442= (on ENST00000312481; = p.V2438= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/313 reads (11%) | called by muse, mutect2, varscan2
- DOCK2 | c.507C>T p.D169= | Silent (SNP) | VAF 16/189 reads (8%) | catalogued as rs202075394, COSV56951015; called by muse, mutect2
- FLII | c.2097C>A p.L699= | Silent (SNP) | VAF 33/132 reads (25%) | called by muse, mutect2, varscan2
- GPR142 | c.1059C>T p.G353= | Silent (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- GREB1L | c.1347C>T p.S449= | Silent (SNP) | VAF 33/231 reads (14%) | catalogued as rs769947250; called by muse, mutect2, varscan2
- SLC6A11 | c.912G>A p.T304= | Silent (SNP) | VAF 33/297 reads (11%) | catalogued as rs371390454; called by muse, mutect2, varscan2
- SYCP2L | c.663C>G p.L221= | Silent (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- ADAD2 | c.419-176C>A | Intron (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2
- CCNF | c.1219-40C>G | Intron (SNP) | VAF 17/125 reads (14%) | called by muse, mutect2, varscan2
- LILRB2 | c.1360+31C>T | Intron (SNP) | VAF 18/67 reads (27%) | catalogued as rs565888183; called by muse, mutect2, varscan2
- LINC00840 | n.293G>A | RNA (SNP) | VAF 45/281 reads (16%) | called by muse, mutect2, varscan2
- LINC02876 | n.499T>A | RNA (SNP) | VAF 27/267 reads (10%) | called by muse, mutect2, varscan2
- LYRM9 | c.219+133C>G | Intron (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- RIT2 | c.426+2860C>T | Intron (SNP) | VAF 17/270 reads (6%) | catalogued as COSV99950815; called by muse, mutect2
- TTN | c.10361-5046A>C | Intron (SNP) | VAF 23/303 reads (8%) | called by muse, mutect2
